Somatic mutation profile of tumor specimen ALCH-B3JO-TTP1-A (aliquot ALCH-B3JO-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3JO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.6 years (22,488 days).
Specimen ALCH-B3JO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8847125-ed41-4744-979b-e10937ffe2ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JO-NB1-A (Blood Derived Normal), aliquot ALCH-B3JO-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6465bb46-feab-4eaa-84e9-2e373ed4372a

The open-access MAF lists 299 somatic variants for this specimen: 206 protein-altering or splice-affecting, 57 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 57, Intron 22, Nonsense Mutation 11, Frame Shift Del 5, Splice Region 5, 3'UTR 4, 5'UTR 4, Splice Site 3, RNA 3, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 152/383 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763804037, CM970251, COSV100446243, COSV58683273, COSV58688196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 100/242 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 122/282 reads (43%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1483062806, COSV53971454; called by muse, mutect2, varscan2
- AC008397.2 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 484/732 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99441524; called by muse, mutect2, varscan2
- AGBL3 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 62/465 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV99310523; called by muse, varscan2
- AKR1A1 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61087522, COSV61087746; called by muse, mutect2, varscan2
- ANKRD30A | c.2967G>T p.M989I (on ENST00000611781; = p.M933I on NM_052997.2) | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64602934; called by muse, varscan2
- APCS | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54817203; called by muse, mutect2, varscan2
- CCDC18 | c.3461G>A p.R1154H (on ENST00000343253 / NM_001306076.1; = p.R1155H on NM_206886.4) | Missense Mutation (SNP) | VAF 125/580 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs771005543; called by muse, mutect2, varscan2
- CDH10 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 125/900 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760804087, COSV52572298, COSV52585105; called by muse, mutect2, varscan2
- CFAP47 | c.4174T>C p.S1392P | Missense Mutation (SNP) | VAF 119/221 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57976373; called by muse, mutect2, varscan2
- CNOT1 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV57769883, COSV57780500; called by muse, mutect2, varscan2
- CRTC2 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1488509633; called by muse, mutect2, varscan2
- DAB1 | c.1231G>A p.A411T (on ENST00000371231; = p.A378T on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1557545876; called by muse, mutect2, varscan2
- DENND2C | c.1997A>G p.H666R (on ENST00000393274 / NM_001256404.2; = p.H609R on NM_198459.4) | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67923823; called by muse, mutect2, varscan2
- DPPA4 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 181/579 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59509458; called by muse, mutect2, varscan2
- ENGASE | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs200719249; called by muse, mutect2, varscan2
- ERVV-1 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV74082800; called by muse, mutect2, varscan2
- ERVV-1 | c.1279G>T p.V427F | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs933869455; called by muse, mutect2, varscan2
- ESYT2 | c.1369G>C p.E457Q (on ENST00000613624; = p.E381Q on NM_020728.3) | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753687265; called by muse, mutect2, varscan2
- ETV1 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs779524119; called by muse, mutect2
- FAT4 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV67882083; called by muse, mutect2, varscan2
- GRIN2C | c.3490G>C p.V1164L | Missense Mutation (SNP) | VAF 163/622 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs747109637; called by muse, mutect2, varscan2
- HS6ST3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as rs1425161456; called by muse, mutect2, varscan2
- KATNAL2 | c.945C>G p.F315L (on ENST00000356157 / NM_001353899.1; = p.F243L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55303524; called by muse, mutect2, varscan2
- KLHL32 | c.1278G>T p.W426C | Missense Mutation (SNP) | VAF 246/644 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987260, COSV65112315; called by muse, mutect2, varscan2
- KRTAP10-3 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100553348; called by muse, mutect2, varscan2
- MAGEB2 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs759031616; called by muse, varscan2
- MAGEL2 | c.3656C>A p.A1219E | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs773964986, COSV58568628; called by muse, mutect2, varscan2
- MGAM | c.2443C>A p.L815I | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.354); catalogued as COSV72073633, COSV72074212; called by muse, mutect2, varscan2
- MUC5AC | c.16574C>G p.P5525R | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as rs777192292; called by muse, mutect2, varscan2
- MYBPC1 | c.150G>T p.Q50H (on ENST00000550270 / NM_206820.2; = p.Q75H on NM_002465.4) | Missense Mutation (SNP) | VAF 224/785 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.547); catalogued as COSV100638001; called by muse, mutect2, varscan2
- NCAN | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV53048184; called by muse, mutect2, varscan2
- NFIB | c.864C>G p.D288E | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.983); catalogued as rs1479600775; called by muse, mutect2, varscan2
- NIPBL | c.5917C>G p.Q1973E | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868722572, COSV56955239; called by muse, mutect2, varscan2
- NPR1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 52/508 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64117530; called by muse, mutect2, varscan2
- NSUN2 | c.58del p.E20Rfs*59 | Frame Shift Del (DEL) | VAF 97/548 reads (18%) | catalogued as COSV52954050; called by mutect2, pindel, varscan2
- OR10G2 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV73390358; called by muse, mutect2, varscan2
- PARP8 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 9/95 reads (9%) | catalogued as COSV55866776; called by muse, mutect2, varscan2
- PCK1 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 125/409 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1409004157; called by muse, mutect2, varscan2
- PCSK4 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763516853; called by muse, mutect2, varscan2
- PLCG1 | c.513-3C>G | Splice Region (SNP) | VAF 9/202 reads (4%) | catalogued as COSV99718360; called by muse, mutect2
- PLXNC1 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 108/417 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as rs779819475, COSV51574251; called by muse, mutect2, varscan2
- PPP1R8 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as rs1318995432; called by muse, mutect2, varscan2
- PRSS36 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs768201640, COSV51637922; called by muse, mutect2, varscan2
- PSAP | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 248/646 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV99818680; called by muse, mutect2, varscan2
- PTPN22 | c.916A>G p.S306G (on ENST00000359785 / NM_001193431.2; = p.S251G on NM_012411.5) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.199); catalogued as rs776839843; called by muse, mutect2, varscan2
- PTPRD | c.3100G>T p.V1034L | Missense Mutation (SNP) | VAF 123/337 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100643651, COSV61945042; called by muse, mutect2, varscan2
- SEPTIN6 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 149/230 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774447993, COSV59713107; called by muse, mutect2, varscan2
- SETD2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57436529; called by muse, varscan2
- SHARPIN | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 200/377 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757638960; called by muse, mutect2, varscan2
- SHISA3 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 112/694 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950938437; called by muse, mutect2, varscan2
- SIPA1L2 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53392325; called by muse, mutect2, varscan2
- SLAMF9 | c.520dup p.D174Gfs*2 | Frame Shift Ins (INS) | VAF 323/1135 reads (28%) | catalogued as rs759108348; called by mutect2, pindel, varscan2
- SLC18A2 | c.53C>G p.S18W | Missense Mutation (SNP) | VAF 140/881 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556880835; called by muse, mutect2, varscan2
- SLC27A6 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99322658; called by muse, mutect2
- SP100 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV50992063; called by muse, mutect2, varscan2
- SPATA31A6 | c.3744C>A p.H1248Q | Missense Mutation (SNP) | VAF 475/945 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs550048106, COSV60534424; called by muse, mutect2, varscan2
- STAB2 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1480469258; called by muse, mutect2, varscan2
- SYT12 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 211/618 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.203); catalogued as COSV101211021; called by muse, mutect2, varscan2
- TRIM9 | c.2056A>T p.N686Y | Missense Mutation (SNP) | VAF 183/486 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030190; called by muse, mutect2, varscan2
- USP29 | c.2555C>G p.A852G | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.88); catalogued as COSV99518498; called by muse, varscan2
- USP54 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 103/323 reads (32%) | catalogued as rs766013576, COSV60439885; called by muse, mutect2, varscan2
- WDR46 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1278924753; called by muse, mutect2, varscan2
- WDR81 | c.3761C>A p.T1254K (on ENST00000409644 / NM_001163809.2; = p.T203K on NM_152348.4) | Missense Mutation (SNP) | VAF 124/302 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774952561; called by muse, varscan2
- ZADH2 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV59268611; called by muse, mutect2, varscan2
- ZFP36L2 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 594/1779 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56698818; called by muse, mutect2, varscan2
- ZNF804A | c.1849C>A p.R617S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56459328; called by muse, mutect2, varscan2
- AASDHPPT | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB11 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS2 | c.3455C>A p.T1152K | Missense Mutation (SNP) | VAF 118/876 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADAP2 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 120/399 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL2 | c.3497-1G>T p.X1166_splice | Splice Site (SNP) | VAF 133/357 reads (37%) | called by muse, mutect2, varscan2
- ADGRL3 | c.301G>T p.E101* (on ENST00000506720 / NM_001322402.2; = p.E33* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- ADGRL4 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); called by muse, varscan2
- AGAP2 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 32/1150 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); called by muse, mutect2
- AMBN | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AMELY | c.185C>A p.P62Q (on ENST00000383036 / NM_001364814.1; = p.P48Q on NM_001143.1) | Missense Mutation (SNP) | VAF 125/235 reads (53%) | SIFT tolerated (0.83); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANKRD16 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOBEC4 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ARHGAP10 | c.210G>T p.E70D | Missense Mutation (SNP) | VAF 95/775 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ARHGEF28 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPDH | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BBS10 | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- BRD2 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BRD7 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP1 | c.441A>T p.K147N | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- C5AR1 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CASZ1 | c.3919_3922del p.C1307Sfs*10 | Frame Shift Del (DEL) | VAF 63/525 reads (12%) | called by mutect2, pindel, varscan2
- CCDC102B | c.1233G>T p.M411I | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- CDC14C | c.740A>T p.Y247F (on ENST00000428251; = p.Y140F on NM_152627.3) | Missense Mutation (SNP) | VAF 174/591 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDCA2 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CDON | c.3277-1G>C p.X1093_splice | Splice Site (SNP) | VAF 46/588 reads (8%) | called by muse, mutect2
- CFAP44 | c.3199C>A p.P1067T | Missense Mutation (SNP) | VAF 236/809 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRDL2 | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CHRNG | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 103/540 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CLEC4C | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CNOT1 | c.5195T>C p.I1732T | Missense Mutation (SNP) | VAF 70/455 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- COL12A1 | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- COL5A2 | c.3377C>A p.P1126H | Missense Mutation (SNP) | VAF 128/521 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPN2 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNNA2 | c.2359C>A p.H787N | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2
- CTNNA3 | c.162A>C p.R54S | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, varscan2
- CXCR4 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CYP4F8 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DDX43 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- DENND2A | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMRTA2 | c.511G>T p.G171* | Nonsense Mutation (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- DMXL1 | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- DOCK2 | c.5334C>A p.N1778K | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK7 | c.4830T>G p.N1610K (on ENST00000635253 / NM_001367561.1; = p.N1579K on NM_033407.3) | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EBF4 | c.295G>T p.E99* (on ENST00000609451; = p.E95* on NM_001110514.1) | Nonsense Mutation (SNP) | VAF 70/213 reads (33%) | called by muse, mutect2, varscan2
- ELMOD2 | c.554C>G p.T185S | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- FASLG | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 181/606 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPR3 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 42/552 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FRAS1 | c.1881C>G p.S627R | Missense Mutation (SNP) | VAF 130/679 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- GALNTL6 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2
- GAP43 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- GGT5 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GLIS1 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 144/873 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- GOLT1B | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 73/659 reads (11%) | called by muse, mutect2, varscan2
- GPR158 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 166/515 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRID2IP | c.2224T>A p.Y742N | Missense Mutation (SNP) | VAF 180/575 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HOXA2 | c.80_81del p.P27Rfs*3 | Frame Shift Del (DEL) | VAF 455/1739 reads (26%) | called by mutect2, pindel, varscan2
- HTR2A | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IBSP | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- IGLV10-54 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IGSF21 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 70/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IPO9 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 210/596 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ITGAD | c.2704A>C p.N902H | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KBTBD11 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 125/229 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNB1 | c.73_80del p.R25Gfs*48 | Frame Shift Del (DEL) | VAF 92/348 reads (26%) | called by mutect2, pindel, varscan2
- KLHL36 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KRTAP10-6 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 112/644 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LHX2 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LUC7L2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- MAGI2 | c.2178C>A p.S726R | Missense Mutation (SNP) | VAF 126/477 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MALSU1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 92/439 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MDH2 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MEGF10 | c.2428T>A p.C810S | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MIOS | c.2612A>T p.E871V | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, varscan2
- MTNR1B | c.85_86del p.R29Afs*47 | Frame Shift Del (DEL) | VAF 73/203 reads (36%) | called by pindel, varscan2
- MYH1 | c.5283G>T p.K1761N | Missense Mutation (SNP) | VAF 149/414 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYLK2 | c.319A>G p.S107G | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEURL4 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 106/304 reads (35%) | called by muse, mutect2, varscan2
- NLRC5 | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NPHS1 | c.2316G>T p.M772I | Missense Mutation (SNP) | VAF 133/612 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NT5C | c.174+4G>T | Splice Region (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- OR1C1 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); called by mutect2, varscan2
- OR56A1 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OR5M8 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OTOG | c.5238G>T p.M1746I | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.1735T>C p.S579P (on ENST00000547103; = p.S570P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDH15 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 115/362 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PCDHGA1 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHACTR4 | c.289A>C p.K97Q (on ENST00000373839 / NM_001350159.2; = p.K107Q on NM_023923.4) | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PRKG1 | c.2061A>C p.*687Yext*16 | Nonstop Mutation (SNP) | VAF 55/133 reads (41%) | called by muse, mutect2, varscan2
- PRR14L | c.5674G>T p.G1892C | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR4 | c.65-5C>A | Splice Region (SNP) | VAF 153/420 reads (36%) | called by muse, mutect2, varscan2
- PRRC2C | c.1512G>T p.E504D (on ENST00000367742; = p.E502D on NM_015172.4) | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PRRT4 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 298/903 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PYY | c.269+3A>T | Splice Region (SNP) | VAF 87/308 reads (28%) | called by muse, mutect2, varscan2
- RBP3 | c.3052C>G p.Q1018E | Missense Mutation (SNP) | VAF 220/578 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- REELD1 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 174/388 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, varscan2
- RGL1 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 73/715 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- RPL10L | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- RPS6KA6 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.2927A>G p.Y976C | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- S100A7L2 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SAGE1 | c.2302A>T p.T768S | Missense Mutation (SNP) | VAF 169/271 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SDS | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 27/333 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEPSECS | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); called by muse, mutect2
- SERPINB9 | c.723+1G>T p.X241_splice | Splice Site (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2
- SFXN5 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SIGLEC12 | c.754A>T p.R252* (on ENST00000291707 / NM_053003.4; = p.R134* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 137/301 reads (46%) | called by muse, mutect2, varscan2
- SLC22A6 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 216/517 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMIM24 | c.180-6C>G | Splice Region (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- SMYD1 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SPATA16 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPRR2A | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 146/772 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SSUH2 | c.514G>C p.A172P | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, varscan2
- SYNE1 | c.3280G>C p.V1094L (on ENST00000367255 / NM_182961.4; = p.V1101L on NM_033071.3) | Missense Mutation (SNP) | VAF 88/550 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF1A | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, varscan2
- TAOK2 | c.1107C>A p.N369K | Missense Mutation (SNP) | VAF 120/644 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, varscan2
- TAS2R3 | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, varscan2
- TFAP2E | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THSD7A | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- TMEM71 | c.749C>T p.A250V (on ENST00000523829 / NM_001382398.1; = p.A231V on NM_144649.3) | Missense Mutation (SNP) | VAF 268/1338 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TRIP11 | c.2135A>G p.E712G | Missense Mutation (SNP) | VAF 378/795 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TSPAN13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2
- TTN | c.17033A>G p.N5678S (on ENST00000591111; = p.N4751S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.13198G>T p.A4400S (on ENST00000591111; = p.A4354S on NM_003319.4) | Missense Mutation (SNP) | VAF 49/171 reads (29%) | PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- UGT2A3 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- USP9X | c.3842_3843dup p.E1282Tfs*11 | Frame Shift Ins (INS) | VAF 78/184 reads (42%) | called by pindel, varscan2
- UTS2B | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 140/413 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZAN | c.2321C>G p.T774S | Missense Mutation (SNP) | VAF 100/451 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZBTB37 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 135/482 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZFAND3 | c.664A>C p.I222L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZFP28 | c.1353T>A p.N451K | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.017); called by muse, mutect2
- ZFP36L2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 217/716 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF527 | c.446A>C p.Q149P | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF546 | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ZNF716 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF735 | c.1155A>T p.E385D | Missense Mutation (SNP) | VAF 136/511 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF804A | c.2431A>G p.K811E | Missense Mutation (SNP) | VAF 129/492 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BRD8 | c.1212G>C p.V404= (on ENST00000254900 / NM_139199.2; = p.V477= on NM_006696.4) | Silent (SNP) | VAF 123/287 reads (43%) | catalogued as COSV50145033; called by muse, mutect2, varscan2
- BTRC | c.777C>T p.D259= (on ENST00000370187 / NM_033637.4; = p.D223= on NM_003939.5) | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as rs371692654; called by muse, mutect2, varscan2
- CAD | c.2244C>T p.F748= | Silent (SNP) | VAF 57/391 reads (15%) | catalogued as rs1329424559, COSV99255604; called by muse, mutect2, varscan2
- CDC14C | c.420C>T p.S140= (on ENST00000428251; = p.S33= on NM_152627.3) | Silent (SNP) | VAF 116/549 reads (21%) | called by muse, mutect2, varscan2
- CES5A | c.660G>A p.V220= | Silent (SNP) | VAF 97/386 reads (25%) | called by muse, mutect2, varscan2
- DIS3L2 | c.543C>T p.I181= | Silent (SNP) | VAF 90/294 reads (31%) | called by muse, mutect2, varscan2
- DNAH2 | c.1962G>T p.T654= | Silent (SNP) | VAF 121/382 reads (32%) | catalogued as COSV101209498; called by muse, mutect2, varscan2
- DOCK1 | c.1122C>G p.V374= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- DTWD1 | c.222T>G p.V74= | Silent (SNP) | VAF 110/255 reads (43%) | called by muse, mutect2, varscan2
- ENPP2 | c.2223T>C p.Y741= (on ENST00000075322 / NM_001040092.3; = p.Y793= on NM_006209.5) | Silent (SNP) | VAF 106/234 reads (45%) | called by muse, mutect2, varscan2
- EPHA6 | c.2910T>A p.P970= | Silent (SNP) | VAF 46/291 reads (16%) | called by muse, mutect2, varscan2
- ERRFI1 | c.1161G>A p.K387= | Silent (SNP) | VAF 82/353 reads (23%) | catalogued as COSV66310818; called by muse, mutect2, varscan2
- FAM124B | c.384G>A p.V128= | Silent (SNP) | VAF 29/191 reads (15%) | catalogued as COSV66271789; called by muse, mutect2, varscan2
- FNDC3B | c.1227C>T p.I409= | Silent (SNP) | VAF 68/686 reads (10%) | catalogued as rs1206930928; called by muse, mutect2
- GPR152 | c.951C>G p.L317= | Silent (SNP) | VAF 60/265 reads (23%) | called by muse, mutect2, varscan2
- GUCY2C | c.1185G>A p.L395= | Silent (SNP) | VAF 29/243 reads (12%) | called by muse, varscan2
- HDAC9 | c.2799T>C p.F933= | Silent (SNP) | VAF 71/217 reads (33%) | catalogued as COSV67777701; called by muse, mutect2, varscan2
- IL17RD | c.1740G>A p.E580= | Silent (SNP) | VAF 164/422 reads (39%) | called by muse, mutect2, varscan2
- INO80B | c.12G>C p.L4= | Silent (SNP) | VAF 149/626 reads (24%) | called by muse, mutect2, varscan2
- INSL3 | c.78C>T p.T26= | Silent (SNP) | VAF 325/444 reads (73%) | called by muse, mutect2, varscan2
- ITGAD | c.1896C>A p.A632= | Silent (SNP) | VAF 86/483 reads (18%) | called by muse, mutect2, varscan2
- KIF2B | c.675G>A p.Q225= | Silent (SNP) | VAF 79/296 reads (27%) | catalogued as rs769864241; called by muse, mutect2, varscan2
- KLHL13 | c.1164A>G p.G388= | Silent (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- KLK12 | c.405C>T p.T135= | Silent (SNP) | VAF 30/316 reads (9%) | catalogued as rs746770863, COSV51578176; called by muse, mutect2
- MARCO | c.699T>C p.D233= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as rs757341263; called by muse, mutect2, varscan2
- NRAP | c.4125G>T p.L1375= (on ENST00000359988 / NM_001322945.2; = p.L1340= on NM_006175.4) | Silent (SNP) | VAF 155/643 reads (24%) | called by muse, mutect2, varscan2
- OR2G6 | c.651C>A p.S217= | Silent (SNP) | VAF 60/534 reads (11%) | called by muse, mutect2, varscan2
- OR2L13 | c.504C>T p.C168= | Silent (SNP) | VAF 45/316 reads (14%) | called by muse, mutect2, varscan2
- OVGP1 | c.798C>T p.T266= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- PCIF1 | c.246G>T p.V82= | Silent (SNP) | VAF 84/278 reads (30%) | catalogued as rs774624317; called by muse, mutect2, varscan2
- PHF21B | c.1158G>T p.A386= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as COSV57557618; called by muse, mutect2, varscan2
- PLXNC1 | c.1098C>T p.I366= | Silent (SNP) | VAF 109/406 reads (27%) | catalogued as rs141950146, COSV99312417; called by muse, mutect2, varscan2
- PPP1R3A | c.2712A>G p.S904= | Silent (SNP) | VAF 58/346 reads (17%) | called by muse, mutect2, varscan2
- PREX2 | c.792G>T p.V264= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV55771335, COSV99904875; called by muse, mutect2, varscan2
- ROS1 | c.6012T>C p.F2004= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- SALL1 | c.954A>C p.P318= | Silent (SNP) | VAF 111/538 reads (21%) | called by muse, mutect2, varscan2
- SLC25A10 | c.90C>G p.L30= | Silent (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- SLC7A14 | c.420C>A p.I140= | Silent (SNP) | VAF 458/1146 reads (40%) | called by muse, mutect2, varscan2
- SLC8A2 | c.1725C>T p.D575= | Silent (SNP) | VAF 110/469 reads (23%) | catalogued as rs1243151553; called by muse, mutect2, varscan2
- SPHK1 | c.342C>T p.N114= (on ENST00000392496 / NM_001355139.2; = p.N128= on NM_021972.4) | Silent (SNP) | VAF 178/687 reads (26%) | catalogued as COSV100039199; called by muse, mutect2, varscan2
- SPTA1 | c.15A>G p.P5= | Silent (SNP) | VAF 65/326 reads (20%) | called by muse, mutect2, varscan2
- SYCE1 | c.933C>A p.P311= | Silent (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- SYTL2 | c.2340A>G p.P780= (on ENST00000528231 / NM_001162951.2; = p.P756= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/323 reads (37%) | called by muse, varscan2
- TBR1 | c.1530G>A p.A510= | Silent (SNP) | VAF 134/346 reads (39%) | called by muse, mutect2, varscan2
- TNN | c.150G>T p.V50= | Silent (SNP) | VAF 57/452 reads (13%) | catalogued as COSV99510987; called by muse, mutect2, varscan2
- TNNT2 | c.678G>A p.R226= (on ENST00000236918; = p.R223= on NM_000364.4) | Silent (SNP) | VAF 30/1158 reads (3%) | called by muse, mutect2
- TNRC18 | c.4932G>T p.S1644= | Silent (SNP) | VAF 171/630 reads (27%) | catalogued as COSV68167994; called by muse, mutect2, varscan2
- TUT4 | c.1152A>G p.S384= | Silent (SNP) | VAF 86/489 reads (18%) | catalogued as rs1376967929; called by muse, mutect2, varscan2
- UNC13C | c.1017C>T p.Y339= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV52910359; called by muse, mutect2, varscan2
- WDR19 | c.870T>C p.V290= | Silent (SNP) | VAF 45/158 reads (28%) | called by muse, varscan2
- XKR4 | c.537C>A p.A179= | Silent (SNP) | VAF 104/282 reads (37%) | catalogued as rs776243014, COSV59338507; called by muse, mutect2, varscan2
- ZBTB6 | c.1134G>A p.G378= | Silent (SNP) | VAF 79/256 reads (31%) | called by muse, mutect2, varscan2
- ZDHHC24 | c.135G>C p.P45= | Silent (SNP) | VAF 235/613 reads (38%) | catalogued as rs1476030062; called by muse, mutect2, varscan2
- ZFP36 | c.303T>G p.T101= (on ENST00000594442; = p.T95= on NM_003407.5) | Silent (SNP) | VAF 77/262 reads (29%) | catalogued as rs563794553; called by muse, mutect2, varscan2
- ZNF154 | c.534C>T p.D178= | Silent (SNP) | VAF 38/410 reads (9%) | called by muse, mutect2
- ZNF473 | c.483C>T p.T161= | Silent (SNP) | VAF 50/228 reads (22%) | catalogued as rs745841822, COSV54522021; called by muse, varscan2
- ZNF804B | c.1620A>T p.I540= | Silent (SNP) | VAF 68/263 reads (26%) | called by muse, mutect2, varscan2
- AC073648.1 | n.225G>T | RNA (SNP) | VAF 106/326 reads (33%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-177592C>T | Intron (SNP) | VAF 62/457 reads (14%) | catalogued as rs368214581; called by muse, mutect2, varscan2
- ADH5P5 | chr5:23979986 G>A | 5'Flank (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- CCDC78 | c.766-14C>T | Intron (SNP) | VAF 51/260 reads (20%) | catalogued as rs1277616910; called by muse, mutect2, varscan2
- CELF2 | c.1076-2331G>A | Intron (SNP) | VAF 115/756 reads (15%) | called by muse, mutect2, varscan2
- CYP20A1 | c.601-18A>G | Intron (SNP) | VAF 37/160 reads (23%) | catalogued as rs369886429; called by muse, mutect2, varscan2
- CYP4F8 | c.343+81G>T | Intron (SNP) | VAF 167/640 reads (26%) | called by muse, mutect2, varscan2
- CYYR1 | c.-110C>A | 5'UTR (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2, varscan2
- DNAH10 | c.9645-729C>A | Intron (SNP) | VAF 136/420 reads (32%) | catalogued as rs1215913186; called by muse, mutect2, varscan2
- EBPL | c.171+4701C>T | Intron (SNP) | VAF 52/446 reads (12%) | called by muse, varscan2
- EBPL | c.171+4700C>A | Intron (SNP) | VAF 55/447 reads (12%) | called by muse, varscan2
- FANCF | chr11:22625846 G>T | 5'Flank (SNP) | VAF 156/473 reads (33%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+26849A>C | Intron (SNP) | VAF 112/260 reads (43%) | called by muse, varscan2
- GOLGA3 | c.3267+69G>A | Intron (SNP) | VAF 76/264 reads (29%) | catalogued as rs749681745; called by muse, mutect2, varscan2
- GPSM1 | c.*20G>A | 3'UTR (SNP) | VAF 68/392 reads (17%) | called by muse, varscan2
- KRTAP20-4 | c.-2C>T | 5'UTR (SNP) | VAF 188/771 reads (24%) | called by muse, mutect2, varscan2
- LITAF | c.*170C>T | 3'UTR (SNP) | VAF 94/561 reads (17%) | catalogued as rs1445882978; called by muse, mutect2, varscan2
- LMAN2L | c.508-1089G>T | Intron (SNP) | VAF 94/342 reads (27%) | called by muse, mutect2, varscan2
- LTO1 | c.346-893A>T | Intron (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- MAGEA3 | c.-109T>C | 5'UTR (SNP) | VAF 278/954 reads (29%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1728+13A>T | Intron (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- MAP4 | c.*18C>T | 3'UTR (SNP) | VAF 60/293 reads (20%) | catalogued as rs1315497576; called by muse, mutect2, varscan2
- MORF4 | n.680A>T | RNA (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- MTRNR2L9 | n.10C>G | RNA (SNP) | VAF 65/207 reads (31%) | called by muse, mutect2, varscan2
- MUCL1 | c.-12C>A | 5'UTR (SNP) | VAF 63/419 reads (15%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1172+136A>C | Intron (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- OCIAD1 | c.*31C>T | 3'UTR (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- PCCB | chr3:136334282 C>G | 3'Flank (SNP) | VAF 57/531 reads (11%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2388+7700C>G | Intron (SNP) | VAF 58/156 reads (37%) | called by muse, mutect2, varscan2
- SLC16A7 | c.217+28718C>T | Intron (SNP) | VAF 98/446 reads (22%) | called by muse, mutect2, varscan2
- SLC17A3 | c.598-27C>A | Intron (SNP) | VAF 101/277 reads (36%) | called by muse, mutect2, varscan2
- SLC17A3 | c.598-28C>A | Intron (SNP) | VAF 98/272 reads (36%) | called by muse, mutect2, varscan2
- SPAG16 | c.942+47161A>G | Intron (SNP) | VAF 38/302 reads (13%) | called by muse, mutect2, varscan2
- VRK2 | c.1183-4572G>C | Intron (SNP) | VAF 30/521 reads (6%) | called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 21/338 reads (6%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
- ZNF451 | c.186+1612G>T | Intron (SNP) | VAF 86/213 reads (40%) | called by muse, mutect2, varscan2
